BEATAML1.0 case 2211 — Functional Genomic Landscape of Acute Myeloid Leukemia (BEATAML1.0-COHORT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/488cc9da-aa42-4357-8c87-62f33502736e

Biospecimens (1 sample)
- Sample BA2057R: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Preservation method: Fresh.
